Surgical pathology report (de-identified scan), TCGA case TCGA-24-1849, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1849-01A (Primary Tumor).

[page 1 of 2]
By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Microscopic Description and Comment:

Sections show diffuse involvement of the omentum by high-grade serous carcinoma with numerous psammoma bodies identified. No endocervical, endometrial, or ovarian parenchymal tumor is identified. The serous carcinoma is identified on the serosal surface of the uterus, with myometrial invasion, on the serosal surface of both fallopian tubes, on the serosal surface of the left ovary, in the bladder peritoneum, in the serosal and subserosal tissue of the terminal ileum, and in the serosal and subserosal tissue of the appendix. We understand that intraoperatively no obvious primary tumor mass was identified although extensive omental caking and peritoneal tumor implants were seen, and that clinically a primary peritoneal carcinoma was likely. Overall, the pathologic findings are also consistent with a high-grade primary peritoneal serous adenocarcinoma.

History:

The patient is an [REDACTED] with an elevated CA125, omental caking, and carcinomatosis. Operative procedure: Total abdominal hysterectomy, bilateral salpingo-oophorectomy, tumor debulking, omentectomy, appendectomy, and small bowel resection.

Specimen(s) Received:

A: UTERUS, CERVIX, BILATERAL TUBES AND OVARIES
B: RECTAL TUMOR
C: BLADDER PERITONEUM
D: GASTRIC, COLIC, OMENTUM
E: TUMOR
F: TERMINAL ILEUM
G: APPENDIX

Gross Description:

The specimens are received in seven containers of formalin, each labeled [REDACTED]. The first container is labeled "uterus, cervix, tubes and ovaries." It contains a 7.4 x 2.5 x 2.0 cm uterus. The serosal surface tan and nodular. There is attached 2.7 x 2.8 cm ectocervix with smooth white mucosa. The specimen is opened to show a 2.7 cm endocervical canal with unremarkable tan mucosa. The endometrial cavity measures 2.2 x 0.7 x 0.4 cm. The endometrium is tan with no focal lesions. Further sectioning shows the endometrium measures up to 0.2 cm thick and the myometrium measures up to 0.9 cm thick. The attached right ovary measures 2 x 1.1 x 1.2 cm, has a smooth tan outer surface. Sections show no focal lesions. The right fallopian tube measures 5.1 x 0.8 x 0.6 cm and is grossly unremarkable. The left ovary measures 2.2 x 1.4 x 0.7 cm. The exterior surface is smooth and tan. Sections show no gross abnormalities. The left fallopian tube measures 4.9 x 0.6 x 0.6 cm. It is grossly unremarkable. Labeled A1 - anterior cervix; A2 - posterior cervix; A3 - anterior endomyometrium; A4 - posterior endomyometrium; A5 - right ovary; A6 - right fallopian tube; A7 - left ovary; A8 - left fallopian tube. [REDACTED]

The second container is labeled "rectal tumor." It contains multiple fragments of tan tissue measuring 2.8 x 2.7 x 0.5

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

cm in aggregate. [REDACTED]

The third container is labeled "bladder peritoneum." It contains a piece of tan soft tissue measuring 7.1 x 3.5 x 0.2 cm. The tissue appears nodular in several areas. [REDACTED]

The fourth container is labeled "gastric colic omentum." It contains a 26.8 x 11.5 x 2.7 cm portion of yellow-tan omentum. Sections show a poorly defined firm white-yellow mass measuring 21.2 x 8.5 x 2.5 cm. [REDACTED]

The fifth container is labeled "tumor." It contains a 4.5 x 4.5 x 1.1 cm piece of yellow-tan fibroadipose tissue. Multiple firm white nodules are identified measuring up to 0.5 cm in greatest dimension. [REDACTED]

The sixth container is labeled "terminal ileum." It contains two segments of small bowel. The smaller segment measures 14.1 cm in length, and 1.8 cm in diameter. The serosal surface is tan-brown and dull with several light tan nodules on the surface. There is 12.2 x 3 x 1 cm of attached yellow mesentery. There are numerous light tan nodules throughout the mesentery measuring up to 0.2 cm in greatest dimension. It is opened to show tan mucosa with normal mucosal folds. The bowel wall thickness measures up to 0.4 cm. The larger piece of the segment measures 45 cm in length and 2.2 cm in diameter. The serosal surface is dark brown and features numerous light tan nodules measuring up to 1.1 cm in greatest dimension. There is a 7 x 6 x 1.5 cm portion of attached mesentery. This also features numerous light tan nodules. The specimen is opened to show tan mucosa with normal mucosal folds. The bowel wall thickness measures up to 0.4 cm. Two putative lymph nodes are identified in the mesenteric fat. Labeled F1 and F2 - margins of small piece of bowel; F3 - small segment of bowel wall; F4 - mesenteric fat from small segment of bowel; F5 and F6 - margins from large segment of bowel; F7 and F8 - large segment of bowel wall; F9 - mesenteric fat from large segment of bowel; F10 - putative lymph nodes. [REDACTED]

The seventh container is labeled "appendix." It contains a 2.5 x 0.7 x 0.8 cm appendix with 4 x 3.7 x 0.9 cm of attached yellow fibroadipose tissue. The serosal surface of the appendix is tan with numerous white-tan nodules measuring up to 0.2 cm in greatest dimension. There are several white-tan nodules on the periappendiceal fat as well. Sections of the appendix show a pinpoint lumen with a wall thickness measuring up to 0.2 cm. There are no other focal lesions. Labeled G1 - appendix; G2 - periappendiceal fat with nodule. Jar 1.

Source: NCI Genomic Data Commons file f44974c6-a111-4786-a865-0eba27dbef84 (TCGA-24-1849.A2181913-086C-42A2-99FD-057B17025DEB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).